Somatic mutation profile of tumor specimen TCGA-PQ-A6FI-01A (aliquot TCGA-PQ-A6FI-01A-11D-A31L-08) from TCGA case TCGA-PQ-A6FI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.3 years (25,672 days).
Specimen TCGA-PQ-A6FI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63387b6d-f542-4b7b-9532-e9fd251d21af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PQ-A6FI-10A (Blood Derived Normal), aliquot TCGA-PQ-A6FI-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca727e51-9d6c-4556-bf4e-4aa439e214ff

The open-access MAF lists 170 somatic variants for this specimen: 134 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 33, Nonsense Mutation 8, Frame Shift Ins 4, Splice Site 2, RNA 2, Frame Shift Del 2, Intron 1, Splice Region 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- KMT2D | c.8053C>T p.R2685* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | hotspot (GDC flag); catalogued as rs587783727, COSV56420426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 61/77 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs566907774, COSV59369559; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3502C>T p.R1168C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs779175944, COSV65893322; called by muse, mutect2, varscan2
- AP1G2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 188/259 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58113354; called by muse, mutect2, varscan2
- ARHGEF2 | c.352G>T p.E118* (on ENST00000361247 / NM_001162383.2; = p.E91* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100560689; called by muse, mutect2, varscan2
- BABAM2 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.969); catalogued as COSV59625224; called by muse, mutect2, varscan2
- BCL11A | c.1912C>T p.P638S (on ENST00000335712 / NM_001365609.1; = p.P672S on NM_018014.4) | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs866753474, COSV59632457; called by muse, mutect2, varscan2
- BLM | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV61924823; called by muse, mutect2, varscan2
- BRD4 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs758977685, COSV54587474; called by muse, mutect2, varscan2
- C1orf115 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as rs746388879, COSV54273907; called by muse, mutect2, varscan2
- C20orf27 | c.195G>T p.E65D (on ENST00000379772 / NM_001258429.2; = p.E90D on NM_001039140.3) | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs753235419, COSV53924273; called by muse, mutect2, varscan2
- C7orf57 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV62363066; called by muse, mutect2, varscan2
- CA3 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53410209; called by muse, mutect2, varscan2
- CCT5 | c.1163G>C p.R388T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54724351; called by muse, mutect2, varscan2
- CFAP44 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV55612399; called by muse, mutect2, varscan2
- CHST5 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60339927; called by muse, mutect2, varscan2
- CIZ1 | c.1587_1591del p.E530* | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | catalogued as COSV52972117; called by mutect2, pindel, varscan2
- CREBBP | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as rs1224361693, COSV99270481; called by muse, mutect2, varscan2
- CSF2RB | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV53258485; called by muse, mutect2, varscan2
- DHX9 | c.2653G>C p.A885P | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841509, COSV62360165; called by muse, mutect2, varscan2
- DLGAP2 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs569842232, COSV70099692; called by muse, mutect2
- DNAJA3 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52162382; called by muse, mutect2, varscan2
- DOP1A | c.1897A>T p.S633C | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52711881; called by muse, mutect2, varscan2
- DTNBP1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 98/912 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as COSV59041090; called by muse, mutect2, varscan2
- EPHA5 | c.2549T>C p.I850T | Missense Mutation (SNP) | VAF 77/100 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56650766; called by muse, mutect2, varscan2
- EPHB1 | c.2099T>C p.M700T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67663339; called by muse, mutect2, varscan2
- FAM171A1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1228384798, COSV65315429, COSV65316913; called by muse, mutect2, varscan2
- FCHO2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99821852; called by muse, varscan2
- FGA | c.80T>A p.F27Y | Missense Mutation (SNP) | VAF 70/93 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as CM130347, COSV57397248; called by muse, mutect2, varscan2
- FRG2B | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV71043123; called by muse, mutect2
- FSCN3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); catalogued as rs1378024231, COSV50001242; called by muse, mutect2, varscan2
- FTMT | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV58420574; called by muse, mutect2, varscan2
- GALNT8 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52898279; called by muse, mutect2, varscan2
- GARRE1 | c.3016A>C p.S1006R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as COSV55100562; called by muse, mutect2
- GDF11 | c.830G>C p.G277A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV57690001, COSV57690839; called by muse, mutect2, varscan2
- GNG4 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 118/210 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV63999255; called by muse, mutect2, varscan2
- GPRC5C | c.1180G>T p.V394F (on ENST00000652232; = p.V349F on NM_018653.4) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV61237380; called by muse, mutect2, varscan2
- GRIA1 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV53607732; called by muse, mutect2, varscan2
- GSN | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57998402; called by muse, mutect2, varscan2
- GUCY2F | c.3202A>G p.K1068E | Missense Mutation (SNP) | VAF 237/274 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54303937; called by muse, mutect2, varscan2
- HDAC5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV56819576; called by muse, mutect2, varscan2
- HDAC5 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs1342236477, COSV104388307, COSV56819587; called by muse, mutect2, varscan2
- HECTD4 | c.5080T>A p.C1694S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV66393700; called by muse, mutect2, varscan2
- HECTD4 | c.2977G>T p.A993S | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV61179945; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.91G>C p.E31Q (on ENST00000354667 / NM_031243.3; = p.E19Q on NM_002137.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV61157901; called by muse, mutect2, varscan2
- HSDL2 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52715467; called by muse, mutect2
- ICE2 | c.1835A>G p.Q612R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV55031877; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 80/886 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs773626529; called by muse, mutect2
- JPH2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1427861059, COSV60697274; called by muse, mutect2, varscan2
- KCNQ3 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV66473078; called by muse, mutect2, varscan2
- KMT2B | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52890962; called by muse, mutect2
- KMT2D | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 46/83 reads (55%) | catalogued as CM114115, COSV56424302; called by muse, mutect2, varscan2
- LAMA3 | c.9487G>A p.E3163K (on ENST00000313654 / NM_198129.4; = p.E1554K on NM_000227.6) | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as COSV52536535; called by muse, mutect2, varscan2
- LPCAT3 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV54646146; called by muse, mutect2, varscan2
- LRIG1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs759550136, COSV56240820, COSV56241683; called by muse, mutect2, varscan2
- LRIG1 | c.2047G>C p.A683P | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56241693; called by muse, mutect2, varscan2
- LRRC6 | c.803T>A p.M268K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV51543318; called by muse, mutect2, varscan2
- MASP2 | c.1889G>C p.R630T | Missense Mutation (SNP) | VAF 182/244 reads (75%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV53570212; called by muse, mutect2, varscan2
- MGA | c.3904G>C p.D1302H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV54956241; called by muse, mutect2, varscan2
- MRPS18A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as COSV64522024; called by muse, mutect2, varscan2
- MTIF3 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV63528615; called by muse, mutect2, varscan2
- MTREX | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57926826; called by muse, mutect2, varscan2
- MTX1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.889); catalogued as rs752758999, COSV57427484, COSV57428402; called by muse, mutect2, varscan2
- NAV3 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57071895, COSV57086621; called by muse, mutect2, varscan2
- NCOR2 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772228038, COSV62292874; called by muse, mutect2, varscan2
- NEB | c.17294G>A p.R5765H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs369436489; called by muse, mutect2, varscan2
- NFX1 | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63196159; called by muse, mutect2, varscan2
- NPC1L1 | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV56926255; called by muse, mutect2, varscan2
- NUP210L | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV55149958, COSV55158032; called by muse, mutect2, varscan2
- NUP88 | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV56706084; called by muse, mutect2, varscan2
- ODF2 | c.1462G>T p.D488Y (on ENST00000434106 / NM_153433.2; = p.D464Y on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63547542; called by muse, mutect2, varscan2
- OR52N5 | c.927A>G p.I309M | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57699024; called by muse, mutect2, varscan2
- OR5K2 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV71143237; called by muse, mutect2, varscan2
- OR5L2 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV65724301; called by muse, mutect2, varscan2
- OR7A10 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs1309850230, COSV50166448; called by muse, mutect2, varscan2
- OTUD6B | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV53443125; called by muse, mutect2, varscan2
- PADI2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 97/130 reads (75%) | SIFT tolerated (0.29); PolyPhen benign (0.428); catalogued as rs1379668694, COSV64945975; called by muse, mutect2, varscan2
- PCOLCE | c.1318C>G p.Q440E | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV56158344; called by muse, mutect2, varscan2
- PDE4DIP | c.4148C>G p.S1383* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV100519774, COSV57718114; called by muse, mutect2, varscan2
- PEG3 | c.4465G>C p.D1489H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1161661265, COSV55636815; called by muse, mutect2, varscan2
- PHF3 | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100013458; called by muse, mutect2, varscan2
- PHKA1 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 61/69 reads (88%) | catalogued as COSV100263409, COSV59812254; called by muse, mutect2, varscan2
- PHRF1 | c.4118C>T p.S1373F (on ENST00000264555 / NM_001286581.2; = p.S1372F on NM_020901.4) | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.58); PolyPhen benign (0.244); catalogued as rs746910335, COSV52757167, COSV99199853; called by muse, varscan2
- PLLP | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs1018038560, COSV54658466; called by muse, mutect2, varscan2
- PLXNA4 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105481, COSV58133956; called by muse, mutect2, varscan2
- POLR3GL | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV65215671; called by muse, mutect2, varscan2
- POU2F2 | c.1134C>G p.V378= (on ENST00000526816 / NM_001207025.3; = p.V362= on NM_002698.5) | Splice Region (SNP) | VAF 49/152 reads (32%) | catalogued as COSV60763939; called by muse, mutect2, varscan2
- PPEF1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62995976; called by muse, mutect2, varscan2
- PSG9 | c.1280G>C p.*427Sext*7 | Nonstop Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV99392353; called by muse, mutect2, varscan2
- PTPRN2 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67043269; called by muse, mutect2, varscan2
- RB1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 51/77 reads (66%) | catalogued as CD143491, COSV57297033; called by muse, mutect2, varscan2
- RC3H2 | c.1853A>T p.Y618F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV100605288, COSV61800839; called by muse, mutect2, varscan2
- RGS22 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV62663175; called by muse, mutect2, varscan2
- RIPOR1 | c.1514G>C p.G505A (on ENST00000379312 / NM_001193522.2; = p.G501A on NM_024519.4) | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV50228333; called by muse, mutect2, varscan2
- RPGRIP1L | c.3145G>C p.E1049Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV50908583; called by muse, varscan2
- RPGRIP1L | c.2461G>C p.D821H | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV50908615; called by muse, mutect2, varscan2
- RPTOR | c.2430G>T p.Q810H | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60810340; called by muse, mutect2
- RYR2 | c.12282C>G p.I4094M | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63691261, COSV63693701; called by muse, mutect2, varscan2
- SART3 | c.1406G>T p.R469L (on ENST00000228284; = p.R451L on NM_014706.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV57207974; called by muse, mutect2, varscan2
- SLC35A3 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64516058, COSV64516434; called by muse, mutect2, varscan2
- SLC7A14 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV51583828; called by muse, mutect2, varscan2
- SLITRK2 | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 127/157 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as rs1556945284, COSV59426311; called by muse, mutect2, varscan2
- SUMO1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV66260054; called by muse, mutect2, varscan2
- SUPT6H | c.4416C>G p.F1472L | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58928289; called by muse, mutect2, varscan2
- SYNDIG1 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65235974; called by muse, mutect2, varscan2
- SYNE1 | c.790G>C p.D264H (on ENST00000367255 / NM_182961.4; = p.D271H on NM_033071.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1280668749, COSV55008857; called by muse, mutect2, varscan2
- TAS2R41 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68765426; called by muse, mutect2, varscan2
- TFPI2 | c.89-1G>A p.X30_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as COSV55990948; called by muse, mutect2, varscan2
- TIAM1 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs771021898, COSV54556457; called by muse, mutect2, varscan2
- TIMP4 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs201048395, COSV99826022; called by muse, mutect2, varscan2
- TMEM169 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 115/203 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs748059072, COSV55265541; called by muse, mutect2, varscan2
- TRIM62 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99357827; called by muse, mutect2, varscan2
- TSKS | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55875860; called by muse, mutect2, varscan2
- TXLNB | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV64444397; called by muse, mutect2, varscan2
- UPRT | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV64912130, COSV64912408; called by muse, mutect2, varscan2
- USP15 | c.2230G>C p.D744H (on ENST00000280377 / NM_001351159.2; = p.D715H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV54793811; called by muse, mutect2, varscan2
- USP34 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as rs1012403607, COSV68402400; called by muse, mutect2, varscan2
- VPS13A | c.3616A>G p.R1206G | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62431732; called by muse, mutect2, varscan2
- VPS54 | c.1588A>G p.I530V | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1418698189, COSV55441707; called by muse, mutect2, varscan2
- XKR3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs1482802812; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1402A>G p.K468E | Missense Mutation (SNP) | VAF 63/77 reads (82%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV56273188; called by muse, mutect2, varscan2
- ZNF208 | c.3263A>T p.E1088V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV68107856; called by muse, mutect2, varscan2
- ZNF445 | c.1785A>T p.K595N | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.784); catalogued as rs1002432771, COSV68539017; called by muse, mutect2, varscan2
- ZNF665 | c.334C>T p.H112Y (on ENST00000600412; = p.H177Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV67215675; called by muse, mutect2, varscan2
- CCL5 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPS1 | c.1179dup p.N394Qfs*44 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel
- HRH3 | c.541_543dup p.S182dup | In Frame Ins (INS) | VAF 44/103 reads (43%) | called by mutect2, pindel, varscan2
- KCNH2 | c.3250_3261delinsGG p.P1084Gfs*168 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | called by pindel, varscan2*
- PTPN14 | c.1079dup p.H360Qfs*4 | Frame Shift Ins (INS) | VAF 108/168 reads (64%) | called by mutect2, pindel, varscan2
- SLC30A9 | c.897-25_901del p.X299_splice | Splice Site (DEL) | VAF 38/76 reads (50%) | called by mutect2, pindel
- STAG2 | c.1797dup p.Y600Ifs*35 | Frame Shift Ins (INS) | VAF 34/53 reads (64%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.1316_1317dup p.E440Lfs*19 | Frame Shift Ins (INS) | VAF 33/62 reads (53%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.7773C>G p.L2591= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs141407178; called by muse, mutect2, varscan2
- CCDC190 | c.138G>A p.L46= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV63363062; called by muse, mutect2, varscan2
- CCDC88A | c.3750G>C p.L1250= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99710607; called by muse, mutect2, varscan2
- CCDC9 | c.822C>T p.I274= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs758135209, COSV55721267; called by muse, mutect2, varscan2
- COL12A1 | c.4863C>G p.L1621= | Silent (SNP) | VAF 60/215 reads (28%) | catalogued as COSV59398107; called by muse, mutect2, varscan2
- CUBN | c.6237A>T p.V2079= | Silent (SNP) | VAF 68/85 reads (80%) | catalogued as COSV64718406; called by muse, mutect2, varscan2
- DGKZ | c.2451G>A p.R817= (on ENST00000454345 / NM_001105540.2; = p.R629= on NM_003646.4) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100551600, COSV58986207; called by muse, mutect2, varscan2
- DIDO1 | c.6366C>T p.N2122= | Silent (SNP) | VAF 116/274 reads (42%) | catalogued as COSV56625497; called by muse, mutect2, varscan2
- DIPK2A | c.375C>A p.I125= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs768693814, COSV100237318; called by muse, varscan2
- DYNC1H1 | c.12981C>T p.A4327= | Silent (SNP) | VAF 63/94 reads (67%) | catalogued as rs538662679, COSV64138077; ClinVar: likely benign; called by muse, mutect2, varscan2
- FN3K | c.714C>T p.F238= | Silent (SNP) | VAF 100/336 reads (30%) | catalogued as COSV56182348, COSV56182373; called by muse, mutect2, varscan2
- FOXJ2 | c.54G>A p.L18= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV50819598; called by muse, mutect2, varscan2
- GLYATL2 | c.144C>T p.A48= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1383082402, COSV54850319; called by muse, mutect2, varscan2
- H2BC8 | c.222C>T p.I74= | Silent (SNP) | VAF 93/191 reads (49%) | catalogued as rs767133701, COSV55127109; called by muse, mutect2, varscan2
- HECW2 | c.4542C>A p.L1514= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV53662686; called by muse, mutect2, varscan2
- ITGB2 | c.2334C>T p.F778= (on ENST00000302347; = p.F754= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/174 reads (26%) | catalogued as COSV56610807; called by muse, mutect2, varscan2
- JUNB | c.405C>T p.F135= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV56877707; called by muse, mutect2
- KIAA1549L | c.3747G>C p.V1249= (on ENST00000321505; = p.V1546= on NM_012194.3) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV55775523, COSV99683577; called by muse, mutect2, varscan2
- MCM10 | c.906G>A p.K302= (on ENST00000484800 / NM_182751.3; = p.K301= on NM_018518.5) | Silent (SNP) | VAF 156/217 reads (72%) | catalogued as COSV66334936; called by muse, mutect2, varscan2
- MORF4L2 | c.534G>A p.A178= | Silent (SNP) | VAF 113/135 reads (84%) | catalogued as rs141716716, COSV64611080; called by muse, mutect2, varscan2
- NELL1 | c.162C>T p.A54= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as COSV54277068; called by muse, mutect2, varscan2
- PTCHD4 | c.2037G>A p.V679= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV59779508; called by muse, mutect2, varscan2
- REG1A | c.97C>A p.R33= | Silent (SNP) | VAF 201/389 reads (52%) | catalogued as COSV52069280, COSV52069979; called by muse, mutect2, varscan2
- RGL2 | c.1203C>A p.L401= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV65842404; called by muse, mutect2, varscan2
- SARDH | c.72G>A p.G24= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53834037; called by muse, mutect2, varscan2
- SPTBN4 | c.5109T>G p.S1703= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV58951803; called by muse, mutect2, varscan2
- SUPT5H | c.2199T>C p.R733= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV63240258; called by muse, mutect2, varscan2
- SVIP | c.135A>G p.Q45= | Silent (SNP) | VAF 93/248 reads (38%) | catalogued as COSV62603219; called by muse, mutect2, varscan2
- TMEM132B | c.1491G>A p.V497= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV54756858; called by muse, mutect2, varscan2
- TSPOAP1 | c.1116G>C p.L372= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52110680; called by muse, mutect2, varscan2
- Z83844.2 | c.534G>C p.L178= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV60928411; called by muse, mutect2, varscan2
- ZER1 | c.1695C>T p.F565= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs776701903, COSV52566403; called by muse, mutect2, varscan2
- ZNF77 | c.378T>G p.T126= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV58822064; called by muse, mutect2, varscan2
- DCHS2 | n.69G>A | RNA (SNP) | VAF 16/20 reads (80%) | catalogued as COSV59729258; called by muse, mutect2, varscan2
- GCNT2 | c.926-34974G>A | Intron (SNP) | VAF 60/79 reads (76%) | catalogued as COSV53942898; called by muse, mutect2, varscan2
- OSTCP1 | n.564G>A | RNA (SNP) | VAF 56/199 reads (28%) | called by muse, mutect2, varscan2
